Somatic mutation profile of tumor specimen TARGET-20-PARPBA-09A (aliquot TARGET-20-PARPBA-09A-01D) from TARGET case TARGET-20-PARPBA, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.2 years (84 days).
Specimen TARGET-20-PARPBA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b81890c6-7b73-4644-89ba-ad1bec331508.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARPBA-14A (Bone Marrow Normal), aliquot TARGET-20-PARPBA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/802f2511-49ed-4b48-ac34-487af7bc7725

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MXRA5 | c.3472C>T p.R1158C | Missense Mutation (SNP) | VAF 21/301 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs183322867, COSV54243662, COSV99479043; called by muse, mutect2
